Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A46B, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A46B-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

- PART 1: PROSTATE AND BILATERAL SEMINAL VESICLES, ROBOTIC-ASSISTED RADICAL PROSTATECTOMY -**
- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8 WITH TERTIARY GLEASON PATTERNS 3 AND 5.
- THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.
- THE CARCINOMA INVOLVES APPROXIMATELY 30% OF THE EXAMINED PROSTATE VOLUME.
- THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR RIGHT BASE REGION (SLIDE 1W).
- BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- THE CARCINOMA EXTENDS TO INKED SURGICAL MARGINS IN THE ANTERIOR RIGHT MID (SLIDE 1O), POSTERIOR RIGHT APEX (SLIDE 1U) AND POSTERIOR RIGHT MID (SLIDE 1V).
- ALL OTHER EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- PERINEURAL INVASION IS IDENTIFIED.
- NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- PATHOLOGIC TNM STAGE: pT3a N0 MX.
- TNM HISTOLOGIC GRADE = G#.
- BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 2: LYMPH NODES, PELVIC, BILATERAL, EXCISION -
TEN (10) BENIGN LYMPH NODES.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 3
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS

ICD-O-3

CRCF: adenocarcinoma, acinar 8550/3
path: adenocarcinoma, NOS 8140/3
Site: prostate, NOS C61.9

PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 80%
WEIGHT OF PROSTATE: 38.85gm
TUMOR SIZE: Maximum dimension: 1.4 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: > 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: Yes - Established (> 0.8mm)
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: Widespread tumor involvement at margin
LYMPH NODES EXAMINED: 10
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

fw 9/27/12

[page 2 of 2]
FINAL DIAGNOSIS:

- PART 1: PROSTATE AND BILATERAL SEMINAL VESICLES, ROBOTIC-ASSISTED RADICAL PROSTATECTOMY -**
- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8 WITH TERTIARY GLEASON PATTERNS 3 AND 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 30% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE POSTERIOR RIGHT BASE REGION (SLIDE 1W).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. THE CARCINOMA EXTENDS TO INKED SURGICAL MARGINS IN THE ANTERIOR RIGHT MID (SLIDE 1O), POSTERIOR RIGHT APEX (SLIDE 1U) AND POSTERIOR RIGHT MID (SLIDE 1V).
- H. ALL OTHER EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- M. TNM HISTOLOGIC GRADE = G#.
- N. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 2: LYMPH NODES, PELVIC, BILATERAL, EXCISION -
TEN (10) BENIGN LYMPH NODES.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 3
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	38.85gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	Widespread tumor involvement at margin
LYMPH NODES EXAMINED:	10
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 39063024-f2fb-4102-8b77-bfb30b291649 (TCGA-EJ-A46B.4B418B68-7866-45C1-8728-9D61BF5A9273.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).